Gene-level copy-number profile of tumor specimen TCGA-22-5477-01A from TCGA case TCGA-22-5477, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.9 years (24,055 days).
Specimen TCGA-22-5477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ac920740-b1f9-44b5-a36a-9ef773e2adb6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5477-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1650d9a2-9e4d-4a65-8ea0-849eb2df14c8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 622; copy number 2: 17,557; copy number 3: 12,621; copy number 4: 19,618; copy number 5: 3,578; copy number 6: 3,415; copy number 7: 920; copy number 9: 564; copy number 10: 649; copy number 14: 4; copy number 17: 239; copy number 26: 9; copy number 33: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5477-01A-01D-1631-01): tumor purity 0.73, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr5:148,025,683–148,137,382, 1 gene (within-gene range 0–2): SPINK5.
- chr6:53,561,289–53,665,756, 3 genes (within-gene range 0–2): AL033397.1, LINC01564, KLHL31.
- chr8:3,373,353–3,375,226, 1 gene: AC026991.1.
- chr16:15,790,975–15,932,294, 5 genes: AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,466 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:181,174,484–181,182,208, 1 gene, copy number 10: LINC01732.
- chr2:119,544,432–120,179,119, 6 genes, copy number 9 (within-gene range 4–9): CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5.
- chr2:123,762,171–124,915,287, 5 genes, copy number 14–33 (within-gene range 2–57): PSMD14P1, AC064859.1, RN7SKP102, AC079154.1, CNTNAP5.
- chr3:175,938,929–176,867,838, 9 genes, copy number 26 (within-gene range 7–26): AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209.
- chr3:177,294,442–187,449,450, 239 genes, copy number 17 (broad region; genes not listed).
- chr5:32,888,236–33,298,066, 1 gene, copy number 9 (within-gene range 6–9): AC010343.3.
- chr5:33,008,934–39,572,639, 115 genes, copy number 9 (broad region; genes not listed).
- chr12:66,767–34,166,954, 846 genes, copy number 9–10 (broad region; genes not listed).
- chr12:59,322,765–72,670,758, 244 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
